CCDI case PBBYJZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/b77dfab6-1a3c-420f-813b-c75b194bcd6e

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Epithelioid sarcoma: ICD-O-3 morphology code: 8804/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.0 years (6,209 days).

Biospecimens (3 samples)
- Sample 0DKRCD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKRCP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKRD2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
